Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q7-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT AXILLARY CONTENTS:

**METASTATIC MALIGNANT MELANOMA IN FOUR OF FOUR LYMPH NODES (4/4).
MAXIMUM TUMOR DEPOSIT 35.0 X 20.0 MM.
EXTENSIVE EXTRA NODAL EXTENSION IS PRESENT.**

**METASTATIC MALIGNANT MELANOMA IN FIBROADIPOSE TISSUE, POSSIBLY
REPRESENTING AN ENTIRELY REPLACED LYMPH NODE WITH EXTRANODAL
EXTENSION.**

(B) DORSUM OF LEFT FOREARM, MEDIAL, SKIN PUNCH:

Please see addendum report.

(C) DORSUM OF LEFT FOREARM, LATERAL, SKIN PUNCH:

Please see addendum report.

Entire report and diagnosis completed by

MD

ICD-0-3

Melanoma, NOS 8720/3
Site: lymph node NOS C17.9
p 3/12/19

GROSS DESCRIPTION

(A) LEFT AXILLARY CONTENTS - An ellipse of tan, hair-bearing skin (12.5 x 1.5 cm with an oblique, well-healed scar 3.0 cm) and abundant axillary adipose tissue (14.0 x 6.0 3.5 cm and a crowded, pigmented black to tan tumor nodule is identified, greater than 1.0 cm from the nearest margin of resection (3.5 x 1.5 x 2.0 cm). Five possible lymph nodes are also identified, ranging from 0.4 up to 1.5 cm in greatest diameter.

SECTION CODE: A1-A4, representative sections of larger nodule; A5, section of larger nodule with nearest margin of resection; A6-A8, multiple possible lymph nodes, intact and entirely.

(B) MEDIAL LESION ON DORSUM OF LEFT FOREARM - A tan-white nonoriented punch of skin measuring 0.4 x 0.4 x 0.2 cm. In the surface of the specimen, there is a slightly raised area (possible pigmented lesion) measuring 0.2 x 0.2 cm. The specimen is inked in blue and entirely submitted in B.

(C) LATERAL LESION ON DORSUM OF LEFT FOREARM - A tan-white punch of skin measuring 0.4 x 0.4 x 0.2 cm. The surface of the specimen is grossly unremarkable. The specimen is inked in blue and entirely submitted in C.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

UNQUALIFIED

"Some tests reported here may have been developed and performance characteristics determined by Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

MD

Sample

[page 2 of 2]
ADDENDUM

ADDENDUM

(B) Deeper sections are examined. The diagnosis is:

MELANOCYTIC NEVUS, PREDOMINANTLY JUNCTIONAL TYPE, WITH MODERATE ARCHITECTURAL DISORDER AND MILD TO MODERATE CYTOLOGIC ATYPIA OF MELANOCYTES ("DYSPLASTIC"), EXCISION.

(C) Deeper sections are examined. The diagnosis is:

MELANOCYTIC NEVUS, PREDOMINANTLY JUNCTIONAL TYPE, WITH MODERATE TO SEVERE ARCHITECTURAL DISORDER AND MODERATE TO FOCALLY SEVERE CYTOLOGIC ATYPIA OF MELANOCYTES ("DYSPLASTIC"), EXCISION.

(Although the lesion is small, focally single cells are present and some are not confined to the basal layer.)

SNOMED CODES

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file d1559eac-4cb1-4188-83f4-ff7163ee0f9f (TCGA-D3-A1Q7.6B4EBE5E-8C55-4820-8FB2-317F530A1007.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).